TCGA case TCGA-66-2757 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a02932f3-5606-42a5-aee4-e5b9f5aa1aaa

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 65 years; Vital status: Dead; Days to death: 1,338 days (3.7 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 65.7 years (24,014 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,338 days (3.7 years).
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 788 days (2.2 years); Days to treatment end: 789 days (2.2 years); Treatment dose: 50 Gy; Treatment outcome: Progressive Disease; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 943 days (2.6 years); Days to treatment end: 943 days (2.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 943 days (2.6 years); Days to treatment end: 1,035 days (2.8 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine; Days to treatment start: 1,277 days (3.5 years); Days to treatment end: 1,277 days (3.5 years); Treatment outcome: Progressive Disease.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 68.2 years (24,926 days); Days to diagnosis: 912 days (2.5 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 912 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,338 days (3.7 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 30.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 72; Tobacco smoking onset year: 1959; Tobacco smoking quit year: 2007.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-66-2757-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-66-2757-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
  Slide TCGA-66-2757-01A-01-BS1: Section location: Bottom; Percent tumor cells: 89; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 10.
- Sample TCGA-66-2757-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-66-2757-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.9; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,338 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,338 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 912 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-66-2757-01A-01D-0844-01): tumor purity 0.86, ploidy 1.86, whole-genome doublings 0.
